CCDI case PBBYBW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3664b1fd-7000-46f0-b2bf-a9a34d0cb473

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,174 days).

Biospecimens (2 samples)
- Sample 0DLA0W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA1U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
